Somatic mutation profile of tumor specimen TCGA-44-6147-01A (aliquot TCGA-44-6147-01A-21D-A27T-08) from TCGA case TCGA-44-6147, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 67.4 years (24,631 days).
Specimen TCGA-44-6147-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a47b275-62bc-42a1-8543-65caaacf5ed3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-6147-10A (Blood Derived Normal), aliquot TCGA-44-6147-10A-01D-1753-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/101c7666-42ea-45d9-8288-16a3cbd47274

The open-access MAF lists 232 somatic variants for this specimen: 159 protein-altering or splice-affecting, 69 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 138, Silent 69, Nonsense Mutation 11, Frame Shift Del 5, Intron 2, Splice Region 2, Frame Shift Ins 1, RNA 1, Splice Site 1, 5'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2303G>T p.S768I | Missense Mutation (SNP) | VAF 60/206 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913465, COSV51768106, COSV51821681, COSV51833841; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- KCTD7 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 19/184 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774026720, COSV51877044, COSV99299062; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 38/117 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as rs11540654, CM115383, CM134053, CM984590, COSV52662399, COSV52668419, COSV52680444, COSV53132492; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSM2B | c.1671A>C p.K557N | Missense Mutation (SNP) | VAF 129/460 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61660186; called by muse, mutect2, varscan2
- ADAM11 | c.950G>A p.R317Q | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.113); catalogued as rs750517141, COSV52350141; called by muse, mutect2, varscan2
- ADCY10 | c.4345C>G p.L1449V | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63239583, COSV63240944, COSV63245296; called by muse, mutect2
- ADGRF2 | c.616T>A p.W206R (on ENST00000296862 / NM_001368115.2; = p.W138R on NM_153839.7) | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV57292367; called by muse, mutect2, varscan2
- ALMS1 | c.2445G>T p.E815D | Missense Mutation (SNP) | VAF 30/204 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.106); catalogued as COSV100041528; called by muse, mutect2, varscan2
- ANK1 | c.1667T>A p.L556Q | Missense Mutation (SNP) | VAF 19/219 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55897090; called by muse, mutect2
- AOC1 | c.1453G>A p.V485I | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs765084312, COSV62870429; called by muse, mutect2
- ASB10 | c.122C>G p.S41C | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.237); catalogued as COSV52000955; called by muse, mutect2, varscan2
- ATRX | c.5257A>G p.N1753D | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64884374; called by muse, mutect2, varscan2
- BRINP2 | c.550G>A p.G184R | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.111); catalogued as COSV64178386; called by muse, mutect2, varscan2
- CACNA1A | c.2560G>T p.G854C | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV64195313; called by muse, mutect2, varscan2
- CACNA1E | c.5494G>T p.D1832Y | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62429521; called by muse, mutect2, varscan2
- CARD14 | c.2159G>A p.R720H | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs202094920, COSV60126797; ClinVar: likely benign; called by muse, mutect2, varscan2
- CASZ1 | c.3976C>T p.R1326W | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199630871, COSV59741527; called by muse, mutect2, varscan2
- CCDC141 | c.3343G>T p.E1115* | Nonsense Mutation (SNP) | VAF 11/58 reads (19%) | catalogued as COSV55382394; called by muse, mutect2, varscan2
- CCDC167 | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1447117920; called by muse, mutect2
- CCDC73 | c.1835A>G p.E612G | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.04); catalogued as COSV58805356; called by muse, mutect2, varscan2
- CD101 | c.1473G>T p.W491C | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.961); catalogued as COSV99869248; called by muse, mutect2, varscan2
- CD101 | c.1474G>T p.A492S | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.715); catalogued as COSV99869256; called by muse, mutect2, varscan2
- CDH6 | c.709C>A p.Q237K | Missense Mutation (SNP) | VAF 57/133 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.829); catalogued as COSV54068746; called by muse, mutect2, varscan2
- CDHR2 | c.2042T>A p.V681D | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56145998; called by muse, mutect2, varscan2
- CDK17 | c.890T>C p.I297T | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV54134021; called by muse, mutect2, varscan2
- CEP89 | c.2303G>T p.G768V | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59862509; called by muse, varscan2
- CEP89 | c.2302G>T p.G768C | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99993196; called by muse, varscan2
- CNTN1 | c.703C>A p.R235= | Splice Region (SNP) | VAF 25/164 reads (15%) | catalogued as COSV100751086, COSV61638587; called by muse, mutect2, varscan2
- COL23A1 | c.436T>C p.Y146H | Missense Mutation (SNP) | VAF 79/319 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV66799365; called by muse, mutect2, varscan2
- COL4A1 | c.2312C>T p.A771V | Missense Mutation (SNP) | VAF 13/160 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.063); catalogued as rs748767250, COSV65433248; called by muse, mutect2
- CORO1B | c.1381C>T p.R461W | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs1252641396; called by muse, mutect2, varscan2
- CPA4 | c.277G>T p.D93Y | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV55985261; called by muse, mutect2, varscan2
- CPT1A | c.1798G>T p.G600W | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55761679; called by muse, mutect2, varscan2
- CSF2RB | c.1220G>T p.R407M | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs1342778985, COSV53261278; called by muse, mutect2, varscan2
- CSMD3 | c.7846G>T p.G2616W (on ENST00000297405 / NM_001363185.1; = p.G2512W on NM_052900.3) | Missense Mutation (SNP) | VAF 96/147 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52331340; called by muse, mutect2, varscan2
- CTNNA1 | c.128A>T p.N43I | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.562); catalogued as COSV57081955; called by muse, mutect2, varscan2
- CTTNBP2 | c.2961T>G p.D987E | Missense Mutation (SNP) | VAF 52/156 reads (33%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV50484331; called by muse, mutect2, varscan2
- DCLK1 | c.1774G>T p.D592Y | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV55213373; called by muse, mutect2, varscan2
- DCLK3 | c.401G>T p.G134V | Missense Mutation (SNP) | VAF 66/192 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.942); catalogued as COSV69364876; called by muse, mutect2, varscan2
- DNAH7 | c.5337G>T p.K1779N | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as COSV100415105; called by mutect2, varscan2
- EGFR | c.2305G>T p.V769L | Missense Mutation (SNP) | VAF 58/208 reads (28%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.572); catalogued as rs147149347, COSV51802272, COSV51811749; ClinVar: uncertain significance; called by muse, mutect2
- ENTPD7 | c.1101C>A p.N367K | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0.102); catalogued as rs972834758, COSV65113356; called by muse, mutect2
- EPDR1 | c.470C>G p.A157G | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.259); catalogued as COSV52258762, COSV52262160; called by muse, mutect2, varscan2
- EPPK1 | c.361G>T p.G121C | Missense Mutation (SNP) | VAF 13/145 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV73262240; called by muse, mutect2
- ERN1 | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.158); catalogued as rs1260432454; called by muse, mutect2, varscan2
- EXOC4 | c.2117A>T p.D706V | Missense Mutation (SNP) | VAF 51/174 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.106); catalogued as COSV54124828; called by muse, mutect2, varscan2
- F12 | c.1763C>A p.S588* | Nonsense Mutation (SNP) | VAF 3/29 reads (10%) | catalogued as COSV53693936; called by muse, mutect2
- FAM83B | c.1485G>T p.W495C | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.817); catalogued as COSV60927347; called by muse, mutect2, varscan2
- FFAR1 | c.443G>A p.G148E | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.114); catalogued as COSV99322956; called by muse, mutect2, varscan2
- FGF4 | c.343C>A p.L115M | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV51449277; called by muse, mutect2
- FLG | c.7423G>T p.G2475* | Nonsense Mutation (SNP) | VAF 561/1088 reads (52%) | catalogued as COSV64250568; called by muse, mutect2, varscan2
- FMN2 | c.2523C>A p.H841Q | Missense Mutation (SNP) | VAF 14/185 reads (8%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as COSV60456169; called by muse, mutect2
- FOXL1 | c.1029C>A p.H343Q | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV100206133; called by muse, mutect2, varscan2
- FSCB | c.2296G>T p.A766S | Missense Mutation (SNP) | VAF 52/192 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.494); catalogued as rs1246242313, COSV100468972; called by muse, mutect2, varscan2
- GABRA6 | c.523G>C p.G175R | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50896119; called by muse, mutect2, varscan2
- GPR142 | c.1126G>A p.V376I | Missense Mutation (SNP) | VAF 63/200 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs199997380, COSV59518721, COSV59519491, COSV99046011; called by muse, mutect2, varscan2
- GZMA | c.592G>T p.A198S | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57057915; called by muse, mutect2, varscan2
- H6PD | c.1124A>T p.N375I | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV66232499; called by muse, mutect2, varscan2
- HMCN1 | c.13693delinsTT p.G4565Lfs*17 | Frame Shift Ins (INS) | VAF 11/91 reads (12%) | catalogued as COSV99623534; called by mutect2*, pindel
- IFNLR1 | c.1113G>T p.R371S | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV59527722; called by muse, mutect2, varscan2
- IGKV3-11 | c.304G>T p.D102Y | Missense Mutation (SNP) | VAF 20/208 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758486991; called by muse, mutect2
- ITGA8 | c.1151G>T p.G384V | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV65229184; called by muse, mutect2, varscan2
- ITGA8 | c.1150G>T p.G384W | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65225821; called by muse, mutect2, varscan2
- ITIH6 | c.2668C>A p.P890T | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.093); catalogued as COSV54495150; called by muse, mutect2, varscan2
- KCNH7 | c.266C>A p.S89* | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | catalogued as COSV100036938, COSV59815024; called by muse, mutect2, varscan2
- KCNJ6 | c.223C>A p.R75S | Missense Mutation (SNP) | VAF 118/282 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55713174, COSV55724009; called by muse, mutect2, varscan2
- KCTD19 | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as COSV58575473; called by muse, mutect2, varscan2
- KHDC4 | c.845A>C p.E282A | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64165881; called by muse, mutect2
- KIAA1958 | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 8/151 reads (5%) | SIFT tolerated (0.54); PolyPhen benign (0.081); catalogued as rs1301988440, COSV61722828; called by muse, mutect2
- KLHL36 | c.1378C>T p.R460C | Missense Mutation (SNP) | VAF 24/245 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.893); catalogued as rs925157924; called by muse, mutect2
- KRT9 | c.904C>A p.Q302K | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs769324302; called by muse, mutect2
- KRTAP10-3 | c.112G>T p.A38S | Missense Mutation (SNP) | VAF 66/183 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV100552310, COSV59959098; called by muse, mutect2, varscan2
- LAMB4 | c.3890C>A p.S1297Y | Missense Mutation (SNP) | VAF 63/242 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as COSV52732020; called by muse, mutect2, varscan2
- LUZP4 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 11/298 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782164761, COSV64218745; called by muse, mutect2
- MAP10 | c.1113G>T p.E371D | Missense Mutation (SNP) | VAF 36/301 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV69365164; called by muse, mutect2, varscan2
- MAP2 | c.829G>T p.E277* | Nonsense Mutation (SNP) | VAF 13/90 reads (14%) | catalogued as COSV52309380; called by muse, mutect2, varscan2
- MEIS3 | c.88G>T p.A30S | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as COSV58985076, COSV58985310; called by muse, mutect2, varscan2
- MGAM | c.1230G>T p.Q410H | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72075973; called by muse, mutect2, varscan2
- MMEL1 | c.674C>G p.S225* | Nonsense Mutation (SNP) | VAF 5/89 reads (6%) | catalogued as COSV56526708; called by muse, mutect2
- MSH4 | c.1723A>G p.I575V | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.068); catalogued as COSV54213468; called by muse, mutect2, varscan2
- MTMR14 | c.1007G>T p.R336L | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM065043, COSV56004553, COSV56007889; called by muse, mutect2, varscan2
- MUC17 | c.11840C>A p.T3947N | Missense Mutation (SNP) | VAF 42/181 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as rs1454428134, COSV60305354; called by muse, mutect2, varscan2
- MUC5B | c.9230C>A p.T3077N | Missense Mutation (SNP) | VAF 31/237 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.066); catalogued as rs990420468; called by muse, mutect2, varscan2
- MYO7B | c.1941C>A p.C647* | Nonsense Mutation (SNP) | VAF 11/54 reads (20%) | catalogued as COSV101267952; called by muse, mutect2, varscan2
- NELL2 | c.1339G>T p.G447W | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61586363; called by muse, mutect2, varscan2
- NKX2-5 | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs746315645; called by muse, mutect2, varscan2
- NTNG2 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.995); catalogued as rs529755045, COSV62369093; called by muse, mutect2, varscan2
- OPRL1 | c.654C>A p.C218* | Nonsense Mutation (SNP) | VAF 96/168 reads (57%) | catalogued as rs767233709, COSV61093080; called by muse, mutect2, varscan2
- OR2M4 | c.605G>A p.C202Y | Missense Mutation (SNP) | VAF 82/173 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV60709843; called by muse, mutect2, varscan2
- OR5T2 | c.236T>G p.M79R | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV57591116; called by muse, mutect2
- OR6C2 | c.595C>T p.L199F | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.015); catalogued as rs141026850; called by muse, mutect2
- PARM1 | c.340G>A p.G114S | Missense Mutation (SNP) | VAF 53/134 reads (40%) | SIFT tolerated (0.94); PolyPhen benign (0.012); catalogued as rs34305542; called by muse, varscan2
- PCDH11X | c.338C>A p.A113D | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV53508284; called by muse, mutect2, varscan2
- PCDHA5 | c.2226C>A p.S742R | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.202); catalogued as rs1210626259, COSV100972164; called by muse, mutect2, varscan2
- PCSK6 | c.1761A>T p.E587D | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.755); catalogued as COSV59345265; called by muse, mutect2
- PDE1B | c.1008G>T p.M336I | Missense Mutation (SNP) | VAF 30/233 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54496708; called by muse, mutect2, varscan2
- PEX1 | c.473-2A>T p.X158_splice | Splice Site (SNP) | VAF 18/79 reads (23%) | catalogued as COSV50421750; called by muse, mutect2, varscan2
- PHF20 | c.2232G>C p.Q744H | Missense Mutation (SNP) | VAF 129/204 reads (63%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.993); catalogued as COSV64978119; called by muse, mutect2, varscan2
- PLIN4 | c.2773G>A p.V925I (on ENST00000301286; = p.V940I on NM_001367868.2) | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs150943101, COSV56692789; called by muse, mutect2
- PLPPR4 | c.1024G>T p.D342Y | Missense Mutation (SNP) | VAF 51/155 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV64567841; called by muse, mutect2, varscan2
- PML | c.1648G>A p.G550R | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.73); catalogued as rs374199653, COSV99166824; called by muse, mutect2, varscan2
- PPFIA3 | c.2964C>G p.N988K | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); catalogued as COSV53256388; called by muse, mutect2
- PPM1D | c.418G>T p.A140S | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.246); catalogued as COSV59958225; called by muse, mutect2, varscan2
- PRRC2C | c.4617A>T p.E1539D (on ENST00000367742; = p.E1537D on NM_015172.4) | Missense Mutation (SNP) | VAF 48/85 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV58914159; called by muse, mutect2, varscan2
- PTPRN2 | c.1216C>T p.H406Y | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67061108; called by muse, mutect2, varscan2
- RAB3C | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs764132162, COSV51442889; called by muse, mutect2, varscan2
- ROBO2 | c.2479G>A p.E827K | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs571504400, COSV59942096; called by muse, mutect2, varscan2
- SACS | c.8900G>A p.R2967H | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.866); catalogued as rs777753707; called by muse, mutect2
- SETX | c.142C>A p.H48N | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56395572; called by muse, mutect2, varscan2
- SKIV2L | c.2650G>T p.D884Y | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as COSV61715220; called by muse, mutect2, varscan2
- SMC2 | c.3539C>T p.S1180L | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as COSV53965317; called by muse, mutect2
- SORCS3 | c.1397C>A p.T466K | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.949); catalogued as COSV63826429; called by muse, mutect2, varscan2
- TBC1D9B | c.2146G>A p.G716S | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100783454; called by muse, varscan2
- TLR4 | c.582C>G p.D194E (on ENST00000355622 / NM_138554.5; = p.D154E on NM_003266.4) | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV62924355; called by muse, mutect2, varscan2
- TMEM120A | c.564G>A p.R188= | Splice Region (SNP) | VAF 6/34 reads (18%) | catalogued as rs782743658, COSV100115510; called by muse, mutect2
- TMEM135 | c.637C>T p.H213Y | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as COSV59707117; called by muse, mutect2, varscan2
- TRIM22 | c.955G>T p.D319Y | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV66090672, COSV66091936; called by muse, mutect2
- TSGA10 | c.1668G>C p.Q556H | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61825934; called by muse, mutect2
- TSGA10 | c.1666C>T p.Q556* | Nonsense Mutation (SNP) | VAF 13/73 reads (18%) | catalogued as COSV61825938; called by muse, mutect2
- TSNARE1 | c.202G>T p.A68S | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.175); catalogued as COSV56184735; called by muse, mutect2, varscan2
- TULP1 | c.1546C>A p.L516I | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV57694001; called by muse, mutect2, varscan2
- UROC1 | c.1811G>C p.G604A | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760134412, COSV52039916; called by muse, mutect2, varscan2
- VWA3B | c.868A>C p.S290R | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV68247114; called by muse, mutect2, varscan2
- WDR3 | c.1927C>T p.P643S | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.102); catalogued as rs780090748, COSV60469269; called by muse, mutect2, varscan2
- ZBED9 | c.2452A>T p.S818C | Missense Mutation (SNP) | VAF 50/145 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.52); catalogued as COSV71729802; called by muse, mutect2, varscan2
- ZDBF2 | c.1726T>A p.S576T | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV65630528; called by muse, mutect2
- ZNF226 | c.1127C>T p.S376F | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.757); catalogued as COSV56197085; called by muse, mutect2, varscan2
- ZNF474 | c.202C>A p.L68I | Missense Mutation (SNP) | VAF 78/196 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.06); catalogued as COSV56947867; called by muse, mutect2, varscan2
- ZNF99 | c.2410C>T p.L804F | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs763673738, COSV101233865, COSV68057026; called by muse, mutect2, varscan2
- ZZEF1 | c.2768A>G p.K923R | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1291056581, COSV67560446; called by muse, mutect2, varscan2
- ADRA2A | c.1112C>A p.A371D | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- DMWD | c.1088G>C p.R363P | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNA2 | c.1958_1976del p.G653Vfs*4 | Frame Shift Del (DEL) | VAF 42/222 reads (19%) | called by mutect2, pindel, varscan2
- EXTL1 | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2
- FCGR2C | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.441); called by muse, mutect2
- FOXRED1 | c.371A>T p.N124I | Missense Mutation (SNP) | VAF 7/167 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GADD45A | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GGNBP2 | c.1450G>T p.D484Y | Missense Mutation (SNP) | VAF 70/201 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- HOATZ | c.169C>A p.R57S | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNJ16 | c.254G>A p.W85* | Nonsense Mutation (SNP) | VAF 6/108 reads (6%) | called by muse, mutect2
- KCNT1 | c.1132C>A p.P378T (on ENST00000488444; = p.P397T on NM_020822.3) | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- KRI1 | c.387_430del p.Y130Tfs*28 | Frame Shift Del (DEL) | VAF 34/410 reads (8%) | called by mutect2, pindel
- MUC6 | c.2131del p.Q711Kfs*41 | Frame Shift Del (DEL) | VAF 68/220 reads (31%) | called by mutect2, varscan2
- MUC6 | c.2130C>A p.N710K | Missense Mutation (SNP) | VAF 70/215 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by mutect2, varscan2
- MYO18B | c.985G>T p.D329Y | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR3A2 | c.56C>A p.A19D | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- PSAP | c.1414C>T p.P472S | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- R3HDM1 | c.3037G>A p.A1013T | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RPGRIP1 | c.2250C>A p.Y750* | Nonsense Mutation (SNP) | VAF 7/66 reads (11%) | called by muse, mutect2
- RSF1 | c.2039T>G p.M680R | Missense Mutation (SNP) | VAF 5/108 reads (5%) | SIFT tolerated (0.52); PolyPhen benign (0.006); called by muse, mutect2
- SMC3 | c.1827G>A p.M609I | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- SPATA31A1 | c.1055A>T p.D352V | Missense Mutation (SNP) | VAF 104/526 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, varscan2
- SPATA31A3 | c.406C>A p.Q136K | Missense Mutation (SNP) | VAF 39/564 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2
- TBC1D9B | c.2174C>T p.T725I | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); called by muse, varscan2
- TNNT3 | c.374A>T p.E125V (on ENST00000397301 / NM_001367846.1; = p.E114V on NM_006757.4) | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TRBV3-1 | c.336C>G p.S112R | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRRAP | c.872del p.L291* | Frame Shift Del (DEL) | VAF 28/143 reads (20%) | called by mutect2, pindel, varscan2
- ZFHX3 | c.8602_8633del p.S2868Gfs*7 | Frame Shift Del (DEL) | VAF 40/206 reads (19%) | called by mutect2, pindel
- ZNF284 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.034); called by muse, mutect2
- ABCA6 | c.1302C>T p.F434= | Silent (SNP) | VAF 3/39 reads (8%) | catalogued as COSV52645630; called by muse, mutect2
- ABHD5 | c.396G>A p.V132= | Silent (SNP) | VAF 66/184 reads (36%) | catalogued as rs373148191, COSV50007116; called by muse, mutect2, varscan2
- ACTA1 | c.933C>T p.I311= | Silent (SNP) | VAF 10/248 reads (4%) | catalogued as COSV64202990; called by muse, mutect2
- ALG10 | c.1125A>T p.P375= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as COSV56794348; called by muse, mutect2, varscan2
- ANK2 | c.8832C>A p.T2944= | Silent (SNP) | VAF 85/215 reads (40%) | catalogued as COSV52191080; called by muse, mutect2, varscan2
- ANXA6 | c.879C>T p.F293= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs781611897, COSV100636816; called by muse, mutect2, varscan2
- ARID1A | c.5334A>G p.E1778= | Silent (SNP) | VAF 7/91 reads (8%) | catalogued as rs375160070; called by muse, mutect2
- ATP2B4 | c.96C>A p.L32= | Silent (SNP) | VAF 207/362 reads (57%) | catalogued as COSV58175372, COSV58184476; called by muse, mutect2, varscan2
- ATRNL1 | c.759C>T p.C253= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as rs200296037, COSV61814876; called by muse, mutect2, varscan2
- BEX3 | c.150C>A p.A50= | Silent (SNP) | VAF 17/343 reads (5%) | catalogued as COSV100244237; called by muse, mutect2
- BRINP2 | c.204T>C p.A68= | Silent (SNP) | VAF 28/253 reads (11%) | catalogued as COSV64180577; called by muse, mutect2, varscan2
- CACNA1S | c.1920C>T p.Y640= | Silent (SNP) | VAF 48/518 reads (9%) | catalogued as COSV62944214; called by muse, mutect2
- CDIPT | c.54G>A p.R18= | Silent (SNP) | VAF 23/99 reads (23%) | catalogued as COSV99570137; called by muse, mutect2, varscan2
- CEP89 | c.2301C>T p.D767= | Silent (SNP) | VAF 26/164 reads (16%) | catalogued as rs201311820, COSV59868070; called by muse, varscan2
- CFAP46 | c.6015A>T p.T2005= | Silent (SNP) | VAF 69/261 reads (26%) | catalogued as COSV54160162; called by muse, mutect2, varscan2
- CHRDL2 | c.76C>A p.R26= | Silent (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2, varscan2
- CNTN5 | c.2598G>A p.V866= | Silent (SNP) | VAF 25/98 reads (26%) | catalogued as COSV54361132; called by muse, mutect2, varscan2
- COL16A1 | c.2736C>A p.P912= | Silent (SNP) | VAF 33/197 reads (17%) | catalogued as COSV54712474; called by muse, mutect2, varscan2
- COL19A1 | c.3279T>C p.S1093= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV59589824; called by muse, mutect2, varscan2
- COL22A1 | c.4308G>A p.E1436= | Silent (SNP) | VAF 87/157 reads (55%) | catalogued as COSV57347163, COSV57362679; called by muse, mutect2, varscan2
- COL24A1 | c.1518A>G p.P506= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV65314980; called by muse, mutect2, varscan2
- CRHR2 | c.888G>A p.A296= | Silent (SNP) | VAF 19/257 reads (7%) | catalogued as rs539017617, COSV59265166; called by muse, mutect2
- CSMD2 | c.1825C>T p.L609= | Silent (SNP) | VAF 43/154 reads (28%) | catalogued as rs769998248, COSV53957048; called by muse, mutect2, varscan2
- CTSG | c.99C>A p.P33= | Silent (SNP) | VAF 125/292 reads (43%) | catalogued as COSV53537038; called by muse, mutect2, varscan2
- DCHS1 | c.1728C>A p.P576= | Silent (SNP) | VAF 11/124 reads (9%) | catalogued as COSV100201653; called by muse, mutect2
- DHODH | c.393C>T p.P131= | Silent (SNP) | VAF 8/91 reads (9%) | catalogued as COSV99536801; called by muse, mutect2
- DISP2 | c.2352C>A p.G784= | Silent (SNP) | VAF 65/199 reads (33%) | catalogued as COSV51145547; called by muse, mutect2, varscan2
- DUSP19 | c.259C>T p.L87= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as COSV100700210; called by muse, mutect2, varscan2
- EFNA2 | c.534C>T p.Y178= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs140490619; called by muse, mutect2, varscan2
- FBN2 | c.1473G>T p.L491= | Silent (SNP) | VAF 4/62 reads (6%) | called by muse, mutect2
- FEZ1 | c.1092A>T p.T364= | Silent (SNP) | VAF 11/89 reads (12%) | called by muse, mutect2, varscan2
- FLVCR2 | c.93C>A p.P31= | Silent (SNP) | VAF 144/261 reads (55%) | catalogued as COSV53163737; called by muse, mutect2, varscan2
- FSCB | c.2295G>T p.V765= | Silent (SNP) | VAF 51/190 reads (27%) | catalogued as COSV100468977; called by muse, mutect2, varscan2
- GABRQ | c.1707C>A p.G569= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as COSV64780795, COSV64784100; called by muse, mutect2
- GRM7 | c.297G>C p.V99= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV63173646; called by muse, mutect2, varscan2
- HTR1D | c.246C>A p.T82= | Silent (SNP) | VAF 27/193 reads (14%) | catalogued as COSV100024725; called by muse, mutect2, varscan2
- ISL1 | c.460C>A p.R154= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as COSV57935903; called by muse, mutect2, varscan2
- KCNAB1 | c.930G>A p.G310= (on ENST00000490337 / NM_172160.3; = p.G299= on NM_003471.3) | Silent (SNP) | VAF 21/94 reads (22%) | catalogued as COSV100203986; called by muse, mutect2, varscan2
- KPRP | c.36G>T p.P12= | Silent (SNP) | VAF 89/169 reads (53%) | catalogued as rs761781923, COSV64222236, COSV64223096; called by muse, mutect2, varscan2
- LILRB5 | c.1155G>A p.V385= | Silent (SNP) | VAF 26/101 reads (26%) | catalogued as rs1300117140; called by muse, mutect2, varscan2
- LRP1B | c.9885C>A p.T3295= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as COSV67260856, COSV67279065; called by muse, mutect2, varscan2
- LSP1 | c.528C>A p.P176= | Silent (SNP) | VAF 83/266 reads (31%) | catalogued as COSV61137836; called by muse, mutect2, varscan2
- LUZP2 | c.915A>C p.A305= | Silent (SNP) | VAF 53/161 reads (33%) | catalogued as COSV61219524; called by muse, mutect2, varscan2
- MMP3 | c.1128C>T p.I376= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV55408311; called by muse, mutect2, varscan2
- MSI2 | c.378A>C p.V126= | Silent (SNP) | VAF 20/145 reads (14%) | catalogued as COSV52369308; called by muse, mutect2, varscan2
- MYH3 | c.4800C>T p.S1600= | Silent (SNP) | VAF 21/370 reads (6%) | catalogued as rs551564834, COSV56870453; called by muse, mutect2
- NEUROD4 | c.828C>G p.S276= | Silent (SNP) | VAF 41/258 reads (16%) | catalogued as COSV54474350, COSV54474648; called by muse, mutect2, varscan2
- NSUN2 | c.2280G>A p.P760= | Silent (SNP) | VAF 27/236 reads (11%) | catalogued as rs150472251; called by muse, mutect2, varscan2
- OR1J2 | c.486C>A p.L162= | Silent (SNP) | VAF 28/186 reads (15%) | catalogued as COSV58945409; called by muse, mutect2, varscan2
- OR2M3 | c.495C>T p.S165= | Silent (SNP) | VAF 35/429 reads (8%) | catalogued as COSV71759314; called by muse, mutect2
- OR4M1 | c.453G>T p.G151= | Silent (SNP) | VAF 166/338 reads (49%) | catalogued as COSV60063785; called by muse, mutect2, varscan2
- OR7G1 | c.138C>G p.L46= | Silent (SNP) | VAF 52/181 reads (29%) | catalogued as COSV53319131, COSV99528779; called by muse, mutect2, varscan2
- PCDHA8 | c.60C>A p.L20= | Silent (SNP) | VAF 42/99 reads (42%) | catalogued as COSV65340726; called by muse, mutect2, varscan2
- PCDHB11 | c.2157G>T p.A719= | Silent (SNP) | VAF 80/285 reads (28%) | catalogued as COSV61314045, COSV61314188; called by muse, mutect2, varscan2
- PITX2 | c.858G>A p.L286= (on ENST00000354925 / NM_001204397.1; = p.L293= on NM_000325.6) | Silent (SNP) | VAF 19/73 reads (26%) | called by muse, mutect2, varscan2
- PLA2R1 | c.2544C>T p.L848= | Silent (SNP) | VAF 44/136 reads (32%) | catalogued as rs1560166743, COSV51787435; called by muse, mutect2, varscan2
- PNPLA8 | c.1944A>G p.P648= | Silent (SNP) | VAF 33/115 reads (29%) | catalogued as rs771282623, COSV57555046; called by muse, mutect2, varscan2
- PPP1R12C | c.2127G>T p.A709= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV52386721; called by muse, mutect2
- PRAMEF1 | c.405A>G p.A135= | Silent (SNP) | VAF 74/351 reads (21%) | catalogued as COSV60019394; called by muse, mutect2, varscan2
- PSG7 | c.321G>T p.L107= | Silent (SNP) | VAF 119/937 reads (13%) | catalogued as COSV68446805; called by muse, mutect2, varscan2
- QPCTL | c.270A>T p.P90= | Silent (SNP) | VAF 49/218 reads (22%) | catalogued as COSV99171222; called by muse, mutect2, varscan2
- RHAG | c.729G>T p.T243= | Silent (SNP) | VAF 49/184 reads (27%) | catalogued as COSV57706648; called by muse, mutect2, varscan2
- RIMBP2 | c.1032C>T p.L344= | Silent (SNP) | VAF 21/149 reads (14%) | catalogued as rs1252958705, COSV55485264; called by muse, mutect2, varscan2
- SAMSN1 | c.633G>T p.V211= | Silent (SNP) | VAF 71/174 reads (41%) | catalogued as COSV53478106; called by muse, mutect2, varscan2
- TBCB | c.72C>T p.S24= | Silent (SNP) | VAF 14/37 reads (38%) | called by muse, mutect2, varscan2
- TDG | c.300C>T p.D100= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as COSV57168824; called by muse, mutect2, varscan2
- WSCD1 | c.1254T>A p.I418= | Silent (SNP) | VAF 39/89 reads (44%) | catalogued as rs1392012900, COSV58498706; called by muse, mutect2, varscan2
- ZNF678 | c.1266C>T p.S422= | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as COSV59388946; called by muse, mutect2
- ZNF79 | c.237T>G p.L79= | Silent (SNP) | VAF 47/215 reads (22%) | catalogued as COSV61071986; called by muse, mutect2, varscan2
- C7orf65 | n.359G>A | RNA (SNP) | VAF 15/178 reads (8%) | catalogued as rs750027131; called by muse, mutect2
- CD300LD | chr17:74592514 G>T | 5'Flank (SNP) | VAF 16/80 reads (20%) | called by muse, mutect2, varscan2
- NFASC | c.2471-1392C>T | Intron (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- TTN | c.10360+3063C>T | Intron (SNP) | VAF 9/66 reads (14%) | called by muse, mutect2, varscan2
